TCGA case TCGA-FF-A7CQ — Lymphoid Neoplasm Diffuse Large B-cell Lymphoma (TCGA-DLBC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Mature B-Cell Lymphomas; Primary site: Lymph nodes; Tissue source site: SingHealth. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/f553f1a9-ecf2-4783-a609-6adca7c4c597

Demographics
Sex at birth: male; Race: asian; Ethnicity: not hispanic or latino; Country of residence at enrollment: Singapore; Age at index: 74 years; Vital status: Alive.

Diagnoses (2)
1. Diffuse large B-cell lymphoma, NOS (the primary disease): ICD-O-3 morphology code: 9680/3; ICD-10 code: C83.3; Tissue or organ of origin: Lymph nodes of head, face and neck; Site of resection or biopsy: Lymph nodes of head, face and neck; Classification of tumor: primary; Age at diagnosis: 74.6 years (27,255 days); Year of diagnosis: 2010; AJCC staging edition: 7th; Ann Arbor clinical stage: Stage IV; Ann Arbor B symptoms: Yes; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 298 days; Ann Arbor extranodal involvement: Yes; Max tumor bulk site: Mediastinal lymph nodes; Sites of involvement: Lymph Node, Axillary / Lymph Node, Cervical / Lymph Node, Hilar / Lymph Node, Iliac-Common / Lymph Node, Iliac-External / Lymph Node, Mediastinal / Lymph Node, Mesenteric / Lymph Node, Para-Aortic / Lymph Node, Retroperitoneal / Lymph Node, Splenic / Bladder, NOS / Adrenal gland, NOS / Bone, NOS / Bone marrow / Liver / Pleura / Other.
   Pathology details: Additional pathology findings: Percent follicular component <= 10%.
   Pathology details: Additional pathology findings: Bone marrow concordant histology; Bone marrow malignant cells: Yes; Consistent pathology review: Yes; Greatest tumor dimension: 3.4 cm; Measurement unit: Centimeters.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cyclophosphamide + Doxorubicin + Prednisone + Rituximab + Vincristine; Initial disease status: Initial Diagnosis; Regimen or line of therapy: R-CHOP; Days to treatment start: 5 days; Days to treatment end: 115 days; Number of cycles: 5.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cyclophosphamide + Prednisone + Rituximab + Vincristine; Initial disease status: Initial Diagnosis; Regimen or line of therapy: R-CVP; Days to treatment start: 116 days; Days to treatment end: 137 days; Number of cycles: 1.
   Recorded as not given: adjuvant Radiation Therapy, NOS; Stem Cell Transplantation, NOS.
2. Progression of diagnosis 1 (Diffuse large B-cell lymphoma, NOS), site: Brain, NOS. Age at diagnosis: 75.3 years (27,510 days); Days to diagnosis: 255 days; Prior treatment: Yes.

Follow-up (4 entries)
- Day 255 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Brain, NOS; Days to progression: 255 days.
- Imaging type: PET; Imaging result: Positive; Timepoint: Within 2 Months After Completion of First-Course Treatment.
- ECOG performance status: 3.
- Follow-up contact recording only the day: day 298.

Molecular and laboratory tests
- BCL2 (IHC): Positive.
- BCL2 amplification (FISH): Positive.
- BCL6 (FISH): Normal.
- CCND1 (IHC): Negative.
- CD10 (IHC): Negative.
- CD138 (IHC): Negative.
- CD15 (IHC): Negative.
- CD20 (IHC): Positive.
- IGH (FISH): Normal.
- IRF4 (IHC): Positive.
- MALT1 (FISH): Normal.
- MYC (FISH): Normal.
- PAX5 (FISH): Normal.
- Lactate Dehydrogenase 978 IU [Blood test normal range upper: 380].

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 43.9 kg; Height: 162 cm; BMI: 16.7.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-FF-A7CQ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Initial weight: 70 mg.
  Slide TCGA-FF-A7CQ-01A-01-TS1: Section location: Top; Percent tumor cells: 80; Percent tumor nuclei: 80; Percent normal cells: 10; Percent necrosis: 5; Percent stromal cells: 5; Percent lymphocyte infiltration: 10; Percent monocyte infiltration: 5; Percent neutrophil infiltration: 2.
- Sample TCGA-FF-A7CQ-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Diffuse large B-cell lymphoma (DLBCL) NOS (any anatomic site nodal or extranodal); History neoadjuvant treatment: No; Prospective collection: No; Retrospective collection: Yes; Treatment outcome first course: Stable Disease.
- Stage record, Ann arbor: B symptoms present indicator: Yes.
- Primary pathology: Follicular component percent: < or = 10%; Extranodal involvment other: bladder; Extranodal site involvement: 6; Maximum tumor bulk anatomic site: Paratracheal/Mediastinal; Bone marrow sample histology: Concordant Histology.
- Primary pathology, Lymph node involvement sites: Lymph node involvement site: Axillary; Lymph node involvement site: cervical; Lymph node involvement site: hilar; Lymph node involvement site: Iliac-common; Lymph node involvement site: Iliac-external; Lymph node involvement site: mediastinal; Lymph node involvement site: mesenteric; Lymph node involvement site: para-aortic; Lymph node involvement site: retroperitoneal; Lymph node involvement site: Splenic.
- Primary pathology, Tumor tissue sites: Submitted tumor site: Adrenal; Submitted tumor site: Bone; Submitted tumor site: Bone Marrow; Submitted tumor site: Liver; Submitted tumor site: Pleura/Pleural Effusion; Submitted tumor site: Other Extranodal Site.
- Tests performed: LDH level: 978; Mib 1 positive percent range: 51 - 75%.
- Tests performed, Genetic testing results, Genetic testing result 1: Immunopheotypic analysis tested: CD10 > 30%; Immunophenotypic analysis method: Immunohistochemistry.
- Tests performed, Genetic testing results, Genetic testing result 2: Immunopheotypic analysis tested: BCL2; Immunophenotypic analysis method: Immunohistochemistry.
- Tests performed, Genetic testing results, Genetic testing result 3: Immunopheotypic analysis tested: CD20; Immunophenotypic analysis method: Immunohistochemistry.
- Tests performed, Genetic testing results, Genetic testing result 4: Immunopheotypic analysis tested: MUM1 > 30%; Immunophenotypic analysis method: Immunohistochemistry.
- Tests performed, Genetic testing results, Genetic testing result 5: Immunopheotypic analysis tested: CD138; Immunophenotypic analysis method: Immunohistochemistry.
- Tests performed, Genetic testing results, Genetic testing result 6: Immunopheotypic analysis tested: CD15; Immunophenotypic analysis method: Immunohistochemistry.
- Tests performed, Genetic testing results, Genetic testing result 7: Immunopheotypic analysis tested: Cyclin D1; Immunophenotypic analysis method: Immunohistochemistry.
- Tests performed, Genetic abnormalities, Genetic abnormality testing result 1: Genetic abnormality tested: C-myc; Genetic abnormality tested other: PAX 5.
- Tests performed, Genetic abnormalities, Genetic abnormality testing result 2: Genetic abnormality tested: BCL2; Genetic abnormality tested other: IGH.
- Tests performed, Genetic abnormalities, Genetic abnormality testing result 3: Genetic abnormality tested: BCL6.
- Tests performed, Genetic abnormalities, Genetic abnormality testing result 4: Genetic abnormality tested: MALT1.
- Follow-up form 1: Lost to follow-up: Yes; Treatment outcome first course: Stable Disease.
- Drug treatment 1: Pharmaceutical therapy drug name: Hydroxydaunomycin; Stem cell transplantation: No; Pharmaceutical regimen: Other Pharmaceutical Regimen (please specify); Pharmaceutical regimen other: R-CHOP, R-CVP.
- Drug treatment 3: Pharmaceutical therapy drug name: Prednisolone; Stem cell transplantation: No; Pharmaceutical regimen: Other Pharmaceutical Regimen (please specify); Pharmaceutical regimen other: R-CHOP, R-CVP.
- Drug treatment 4: Pharmaceutical therapy drug name: Oncovin; Stem cell transplantation: No; Pharmaceutical regimen: Other Pharmaceutical Regimen (please specify); Pharmaceutical regimen other: R-CHOP, R-CVP.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 298 days; disease-specific survival: no event (censored), 298 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 255 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-FF-A7CQ-01A-11D-A381-01): tumor purity 0.55, ploidy 2.14, whole-genome doublings 0.
